Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A26C, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A26C-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Melanoma, spindle cell, NOS 8772/3

Site: Skin, back c44.5 *hw* 4/27/11

SPECIMENS:

- A. LEFT AXILLARY CONTENTS
- B. MELANOMA LEFT UPPER BACK
- C. ADDITIONAL LATERAL MARGIN
- D. ADDITIONAL MEDIAL MARGIN

DIAGNOSIS:

- A. CONTENTS OF LEFT AXILLA, DISSECTION:
- TWO OF TWENTY-FIVE LYMPH NODES POSITIVE FOR METASTATIC MELANOMA (2/25).
- EXTRACAPSULAR EXTENSION IS IDENTIFIED
- SEE COMMENT.

- ✓* B. SKIN AND SOFT TISSUE OF LEFT UPPER BACK, EXCISION:
- ULCERATED MALIGNANT MELANOMA, SPINDLE CELL TYPE
- CLARK'S LEVEL V, BRESLOW DEPTH AT LEAST 14 MM
- SURGICAL MARGINS ARE FREE OF MELANOMA
- SEE UPDATED TEMPLATE AND COMMENT
- SOLAR ELASTOSIS AND INCIDENTAL SOLAR LENTIGO

- C. SKIN OF LEFT UPPER BACK, ADDITIONAL LATERAL MARGIN, EXCISION:
- NO RESIDUAL MELANOMA IDENTIFIED.
- SOLAR ELASTOSIS AND SOLAR LENTIGO.

- D. SKIN OF LEFT UPPER BACK, ADDITIONAL MEDIAL MARGIN, EXCISION:
- NO RESIDUAL MELANOMA IDENTIFIED.
- SOLAR ELASTOSIS AND SOLAR LENTIGO.

SPECIMEN(S):

- A. LEFT AXILLARY CONTENTS B. MELANOMA LEFT UPPER BACK C. ADDITIONAL LATERAL MARGIN D. ADDITIONAL MEDIAL MARGIN

CLINICAL HISTORY:

None given

GROSS DESCRIPTION:

A. LEFT AXILLARY CONTENTS

Received fresh and labeled "left axillary contents" is a piece of yellow-tan fatty tissue measuring 18 x 12.5 by up to 4.3 cm and weighing 376 grams. The surface is inked black and the specimen is serially sectioned and there are two enlarged lymph nodes present measuring 7.0 x 5.5 x 3.0 and 3.0 x 2.9 x 1.9 cm. The lymph nodes have a pink-tan coloration throughout.

A1-A2: mid size lymph node that was tissue procured

A3-A4: larger lymph node for tissue procurement

A5-A8: five possible lymph nodes each

A9-A10: four possible lymph nodes each

A11: two possible lymph nodes

A12-A17: one bisected lymph node each

A18-A20: one lymph node

B. MELANOMA LEFT UPPER BACK

Received fresh for tissue procurement labeled with the patient's name designated "B - melanoma left upper back" is a circular procurement of skin with the center packed in surgical dressing measuring 8.5 x 7.4 x 4.7 cm. The specimen is received with orientation, the short suture designating proximal, the long suture designating lateral. The specimen is further orientated to proximal portion-12 o'clock, medial portion-3 o'clock, distal portion-6 o'clock and the lateral portion as 9 o'clock. The specimen is inked as follows: 12 o'clock-red, 3 o'clock-green, 6 o'clock-blue and 9 o'clock-yellow. The deep surgical margin is inked black. On the surface of the specimen there is a brown-tan raised irregular nodular mass measuring 4.6 x 4.3 x 2.5 cm. Cut section of the lesion shows beige-tan firm tissue. The uninvolved skin surface is slightly thickened. The mass approaches the distal margin at a distance of 0.6, the proximal margin at a distance of 2.0, the medial aspect at a distance of 2.1 and the lateral aspect at a

[page 2 of 2]
distance of 1.8 cm. The lesion approaches the deep margin at a distance of 0.7 cm. A portion of the tumor is submitted for tissue procurement. Representative sections are submitted as follows:

- B1-B8: the distal margin from 4 o'clock to 7 o'clock
- B9-B15: the proximal margin from 11 o'clock to 2 o'clock
- B16-B17: sections of lesion and deep margin from the lateral aspect
- B18-B19: representative sections of lesion and deep margin from the medial aspect
- B20-B21: representative sections of lesion and lateral aspect
- B22-B23: representative sections of lesion and medial aspect

C. ADDITIONAL LATERAL MARGIN

Received in formalin labeled with patient name designated "C - additional lateral margin" is an irregular ellipse of brown-tan skin measuring 6.9 x 5.8 and at a depth 1.7 cm. The specimen is received orientated with a stitch designating the lateral margin. The specimen is inked as follows: proximal portion-red, distal portion-blue and the deep surgical margin-black. Representative sections are submitted as follows:

- C1: the lateral margin or tip
- C2: section adjacent to tip
- C3: representative cross section proximal
- C4: representative cross section distal

D. ADDITIONAL MEDIAL MARGIN

Received in formalin in a container labeled with patient name designated "D - additional medial margin" is an irregular beige-tan ellipse of skin measuring 6.0 x 4.1 x 1.3 cm in depth. The specimen is received with orientation-a stitch indicating the medial margin. The specimen is inked as follows: proximal-red, distal-blue and the deep surgical margin is inked black. Representative sections of the specimen are submitted as follows:

- D1: medial tip or margin
- D2: section adjacent to the tip
- D3: cross section of the specimen proximal aspect
- D4: cross section of the specimen with distal aspect

COMMENT:

The melanoma present in the axillary lymph nodes closely resembles the primary tumor of the left upper back. Both show intense S100 staining and rare cells positive for HMB45. MelanA is negative. There is some weak background staining for SMA focally. This is a very spindled melanoma with a nodular growth pattern. Although this melanoma was previously biopsied, the current specimen is much larger and allows for more accurate staging. Because the staging parameters have significantly changed in the current specimen, a revised template is been issued.

REVISED MELANOMA TEMPLATE

Specimen Type:	Excision
Histological Type:	Spindled/nodular
Clark's Level:	V
Thickness:	>14 mm
Host Reaction:	Brisk tumor infiltrating lymphocytes
Mitotic Rate:	7.98/mm ²
Vertical Growth:	Prominent
Angiolymphatic Invasion:	Absent
Ulceration:	Present
Regression:	Absent
Precursor:	Absent
Satellites:	Absent
Margins:	Uninvolved
Distance to Closest Margin:	>1.0 cm (distal)
Lymph Nodes:	Positive (2/25)
Extranodal Extension:	Present
Micrometastasis:	Absent
Pathological Stage:	pT4b N2b Mx

Microscopic/Diagnostic Dictation:., Pathologist
Final Review: Pathologist, "
Final:., Pathologist,

Immunohistochemistry Discrepancy		
Prognostic Factor Discrepancy		
Quality Control/Review Noted		
Case is (re)filed		

Source: NCI Genomic Data Commons file 31f9709f-d4e5-48e4-bb36-e0ee371c0fb7 (TCGA-GN-A26C.5D0A4FFF-76E6-4F84-8F84-141A77E0BB82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).